Somatic mutation profile of tumor specimen TCGA-44-6145-01A (aliquot TCGA-44-6145-01A-11D-1753-08) from TCGA case TCGA-44-6145, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 62.3 years (22,745 days).
Specimen TCGA-44-6145-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b290139c-d657-4e25-a406-6214f6ec704c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-44-6145-10A (Blood Derived Normal), aliquot TCGA-44-6145-10A-01D-1753-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c6704b0e-e31e-4511-9d47-ce8b38ceaf65

The open-access MAF lists 332 somatic variants for this specimen: 258 protein-altering or splice-affecting, 67 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 225, Silent 67, Nonsense Mutation 17, Frame Shift Del 6, Splice Site 5, Intron 4, Splice Region 3, RNA 2, Translation Start Site 1, 3'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 7/30 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- TP53 | c.994-1G>T p.X332_splice | Splice Site (SNP) | VAF 7/25 reads (28%) | hotspot (GDC flag); catalogued as CS002470, CS033842, CS103209, COSV52668116, COSV52746625, COSV52766192; called by muse, mutect2, varscan2
- ABCB5 | c.2259G>T p.Q753H (on ENST00000404938 / NM_001163941.2; = p.Q308H on NM_178559.6) | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV51722176; called by muse, mutect2, varscan2
- ABCC5 | c.1604G>T p.R535L | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs550542220, COSV55589847, COSV55597043; called by muse, mutect2, varscan2
- ABHD16B | c.531C>G p.C177W | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755960974, COSV53861734, COSV99410912; called by muse, mutect2, varscan2
- ACVR1B | c.946G>A p.A316T | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99232065; called by muse, mutect2, varscan2
- ADAMTS18 | c.2189G>T p.G730V | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV51423806; called by muse, mutect2, varscan2
- AKAP9 | c.8480G>T p.G2827V (on ENST00000359028; = p.G2803V on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.91); catalogued as COSV62359023; called by muse, mutect2, varscan2
- ALOX12 | c.1783T>A p.W595R | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.232); catalogued as COSV52352547; called by muse, mutect2, varscan2
- ALOX5 | c.188G>C p.G63A | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100980092, COSV65554848; called by muse, mutect2, varscan2
- AMER3 | c.314C>A p.T105K | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.029); catalogued as COSV58470744; called by muse, mutect2, varscan2
- ANKRD12 | c.4414G>T p.E1472* | Nonsense Mutation (SNP) | VAF 12/58 reads (21%) | catalogued as COSV50853290; called by muse, mutect2, varscan2
- ANO3 | c.2518C>A p.R840S | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56810386; called by muse, mutect2, varscan2
- ASPM | c.719C>T p.S240F | Missense Mutation (SNP) | VAF 29/182 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.091); catalogued as COSV54139871; called by muse, mutect2, varscan2
- ATP8A1 | c.1466C>G p.T489R | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52549546; called by muse, mutect2, varscan2
- B4GALNT4 | c.2611G>T p.E871* | Nonsense Mutation (SNP) | VAF 8/58 reads (14%) | catalogued as COSV57326948; called by muse, mutect2, varscan2
- BMPR1A | c.1276A>G p.I426V | Missense Mutation (SNP) | VAF 21/151 reads (14%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.727); catalogued as rs780148965, COSV100923722; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BMPR2 | c.1357G>T p.V453L | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as COSV65813814; called by muse, mutect2, varscan2
- C12orf42 | c.479A>T p.Q160L | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV59391539; called by muse, mutect2, varscan2
- C7orf33 | c.518G>A p.R173K | Missense Mutation (SNP) | VAF 17/148 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.479); catalogued as COSV61024255; called by muse, mutect2, varscan2
- CA4 | c.370A>T p.K124* | Nonsense Mutation (SNP) | VAF 24/174 reads (14%) | catalogued as COSV56282921; called by muse, mutect2, varscan2
- CDH10 | c.1227G>T p.R409S | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.073); catalogued as COSV52584337, COSV52600066; called by muse, mutect2, varscan2
- CDH9 | c.1236del p.R413Gfs*4 | Frame Shift Del (DEL) | VAF 18/92 reads (20%) | catalogued as COSV50267359; called by mutect2, pindel, varscan2
- CDK17 | c.316G>T p.D106Y | Missense Mutation (SNP) | VAF 4/57 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV54134162; called by muse, mutect2
- CDK8 | c.993G>T p.Q331H | Missense Mutation (SNP) | VAF 22/162 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as COSV67423342; called by muse, mutect2, varscan2
- CERKL | c.1214G>T p.R405M (on ENST00000339098 / NM_001030311.2; = p.R379M on NM_201548.5) | Missense Mutation (SNP) | VAF 31/227 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as COSV59207805, COSV59214411; called by muse, mutect2, varscan2
- CFAP43 | c.1495T>C p.F499L | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53381824; called by muse, mutect2, varscan2
- CFAP65 | c.2318A>T p.H773L | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as COSV58566883; called by muse, mutect2, varscan2
- CFAP65 | c.1955G>T p.S652I | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV100446018, COSV58560424; called by muse, mutect2, varscan2
- CHAMP1 | c.2306G>T p.R769L | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); catalogued as rs376247811, COSV63521905; called by muse, mutect2, varscan2
- CHRNA1 | c.787G>A p.V263I (on ENST00000261007 / NM_001039523.3; = p.V238I on NM_000079.4) | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.506); catalogued as rs1414800603, COSV53682794; called by muse, mutect2, varscan2
- CILP | c.3152C>T p.P1051L | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56028373; called by muse, mutect2, varscan2
- CLCA1 | c.787C>A p.Q263K | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as COSV52331862; called by muse, mutect2, varscan2
- CNTN1 | c.821G>C p.R274P | Missense Mutation (SNP) | VAF 29/156 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV61646272; called by muse, mutect2, varscan2
- CNTNAP4 | c.92G>T p.C31F | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56692369, COSV56702691; called by muse, mutect2, varscan2
- CNTNAP4 | c.1735G>C p.G579R | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs1568326814, COSV100273616, COSV56665258; called by muse, mutect2
- COL17A1 | c.3703C>A p.L1235M | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV62229742; called by muse, mutect2, varscan2
- COL1A2 | c.3332G>T p.G1111V | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.971); catalogued as HM060012, COSV51966994; called by muse, mutect2, varscan2
- COL22A1 | c.4423C>A p.Q1475K | Missense Mutation (SNP) | VAF 79/293 reads (27%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.93); catalogued as rs1250719270, COSV57363202; called by muse, mutect2, varscan2
- COL5A2 | c.1014G>T p.R338S | Missense Mutation (SNP) | VAF 29/196 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.879); catalogued as COSV66415986; called by muse, mutect2, varscan2
- COL6A3 | c.5544C>A p.D1848E | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.138); catalogued as rs531282669, COSV55091689; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPA2 | c.868G>T p.V290L | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV55981599; called by muse, mutect2, varscan2
- CPNE4 | c.508G>T p.D170Y | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV70200746; called by muse, mutect2
- CRIPT | c.251C>A p.A84E | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs758897566, COSV53231670, COSV53232629; called by muse, mutect2, varscan2
- CSGALNACT1 | c.560C>G p.A187G | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.209); catalogued as COSV59984014; called by muse, mutect2
- CSMD1 | c.9262C>A p.P3088T (on ENST00000520002; = p.P3087T on NM_033225.6) | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100151089; called by muse, mutect2
- CSMD3 | c.9241G>T p.A3081S (on ENST00000297405 / NM_001363185.1; = p.A2912S on NM_052900.3) | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52334598; called by muse, mutect2, varscan2
- DAPK3 | c.100G>T p.G34C | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.501); catalogued as COSV56665323; called by mutect2, varscan2
- DAXX | c.1696C>T p.L566F | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.763); catalogued as COSV56473180; called by muse, mutect2, varscan2
- DBN1 | c.831G>A p.E277= | Splice Region (SNP) | VAF 6/47 reads (13%) | catalogued as rs777890271, COSV52793652; called by muse, mutect2, varscan2
- DCDC1 | c.3694G>T p.V1232L (on ENST00000597505 / NM_001367979.1; = p.V339L on NM_020869.3) | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.554); catalogued as COSV100338861; called by muse, varscan2
- DGCR2 | c.1151G>T p.G384V | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99594088; called by muse, mutect2
- DHX32 | c.1535T>G p.M512R | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV52943748; called by muse, mutect2, varscan2
- DHX9 | c.754C>T p.H252Y | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV62362559; called by muse, mutect2, varscan2
- DMD | c.2768C>A p.S923Y | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as COSV100823251; called by muse, mutect2
- DNAH5 | c.8726G>T p.R2909L | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.38); catalogued as COSV54231201, COSV54255638; called by muse, mutect2, varscan2
- DNAH9 | c.3809C>A p.S1270Y | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.492); catalogued as COSV52378120, COSV99308529; called by muse, mutect2, varscan2
- ELF2 | c.1560G>T p.Q520H (on ENST00000379550 / NM_001331036.2; = p.Q460H on NM_006874.4) | Missense Mutation (SNP) | VAF 25/132 reads (19%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV55496269; called by muse, mutect2, varscan2
- ENTPD1 | c.143A>T p.K48M | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV64604659; called by muse, mutect2, varscan2
- EPHA5 | c.2765G>T p.R922M | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56677447; called by muse, mutect2, varscan2
- EPHB6 | c.559G>C p.A187P | Missense Mutation (SNP) | VAF 47/396 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV67421099; called by muse, mutect2, varscan2
- ERP44 | c.658G>T p.D220Y | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as COSV52435613, COSV99316779; called by muse, mutect2, varscan2
- FAM171B | c.740A>T p.E247V | Missense Mutation (SNP) | VAF 22/165 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.055); catalogued as COSV59009222; called by muse, mutect2, varscan2
- FAM71A | c.175G>A p.V59M | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV54237460; called by muse, mutect2, varscan2
- FAS | c.341A>T p.E114V | Missense Mutation (SNP) | VAF 63/424 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1435894576, CS121539, COSV58240242; called by muse, mutect2, varscan2
- FBXL13 | c.307A>G p.K103E | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.916); catalogued as COSV57545243; called by muse, mutect2, varscan2
- FCN2 | c.438G>T p.Q146H | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV52479263; called by muse, mutect2, varscan2
- FRG1 | c.673A>G p.K225E | Missense Mutation (SNP) | VAF 25/237 reads (11%) | SIFT tolerated (0.46); PolyPhen benign (0.045); catalogued as COSV57008773; called by muse, mutect2, varscan2
- FRMPD4 | c.803C>A p.T268N | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as COSV66224333; called by muse, mutect2, varscan2
- FTMT | c.67C>T p.R23C | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs1321899820, COSV100360292, COSV58419974; called by muse, mutect2, varscan2
- GABRB3 | c.1078C>A p.R360= | Splice Region (SNP) | VAF 39/222 reads (18%) | catalogued as COSV100159362, COSV100160423; called by muse, mutect2, varscan2
- GBA3 | c.613T>C p.W205R | Missense Mutation (SNP) | VAF 29/151 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV72438816; called by muse, mutect2, varscan2
- GDAP1L1 | c.695G>T p.G232V | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.299); catalogued as COSV61159119; called by muse, mutect2, varscan2
- GLIPR1 | c.187G>C p.A63P | Missense Mutation (SNP) | VAF 32/221 reads (14%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.723); catalogued as COSV56990663, COSV56993171; called by muse, mutect2, varscan2
- GPR55 | c.847C>A p.L283M | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67408850; called by muse, mutect2, varscan2
- GPRIN1 | c.145C>A p.Q49K | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.639); catalogued as COSV56140877, COSV99992254; called by muse, mutect2, varscan2
- GRAP2 | c.886G>T p.E296* | Nonsense Mutation (SNP) | VAF 11/47 reads (23%) | catalogued as COSV59997345; called by muse, mutect2, varscan2
- GRM5 | c.1880T>A p.L627Q | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs201208612, COSV59632398; called by muse, mutect2, varscan2
- GSDMD | c.267G>C p.Q89H | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV52798395; called by muse, mutect2, varscan2
- HEPH | c.2632G>T p.V878F (on ENST00000343002; = p.V611F on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV57973367; called by muse, mutect2, varscan2
- HIPK1 | c.2056G>C p.A686P | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); catalogued as COSV61250742, COSV61250969; called by muse, mutect2, varscan2
- HMGA2 | c.146G>T p.R49M | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV63592078; called by muse, mutect2, varscan2
- HSPG2 | c.215G>T p.G72V | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65977936; called by muse, mutect2, varscan2
- HYDIN | c.10117G>A p.V3373I | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.027); catalogued as COSV101158719; called by muse, mutect2, varscan2
- IGKV3-7 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1448099747; called by muse, mutect2, varscan2
- IGSF1 | c.2856G>T p.R952S | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV63840750; called by muse, mutect2, varscan2
- IL1F10 | c.154C>G p.R52G | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.471); catalogued as COSV61750678, COSV61751044; called by mutect2, varscan2
- IL1RL1 | c.1066G>A p.E356K | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.214); catalogued as COSV52121030; called by muse, mutect2
- IL31RA | c.352C>A p.P118T | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.048); catalogued as COSV51682556, COSV51685560; called by muse, mutect2, varscan2
- IL36G | c.362G>A p.R121H | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs780697688, COSV52077685; called by muse, mutect2, varscan2
- INSL5 | c.284G>T p.G95V | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.42); catalogued as COSV58788682; called by muse, mutect2, varscan2
- INSR | c.1117G>A p.G373R | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.085); catalogued as COSV57174267; called by muse, mutect2, varscan2
- ITGAD | c.1603C>A p.L535M | Missense Mutation (SNP) | VAF 27/231 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.156); catalogued as COSV66760518; called by muse, mutect2, varscan2
- KCNA2 | c.1310A>C p.K437T | Missense Mutation (SNP) | VAF 28/145 reads (19%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.084); catalogued as COSV60371632; called by muse, mutect2, varscan2
- KCNK2 | c.1139G>T p.C380F (on ENST00000444842 / NM_001017425.3; = p.C365F on NM_014217.4) | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.492); catalogued as rs760985406, COSV67210909; called by muse, mutect2
- KCNK6 | c.859G>T p.V287L | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs778517642, COSV54581344; called by muse, mutect2, varscan2
- KHDC3L | c.620G>T p.R207L | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV64859131, COSV64859608; called by muse, mutect2, varscan2
- KIAA1614 | c.775C>A p.L259M | Missense Mutation (SNP) | VAF 35/205 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as COSV62553890; called by muse, mutect2, varscan2
- KIF21B | c.2686C>A p.R896= | Splice Region (SNP) | VAF 12/68 reads (18%) | catalogued as COSV59753225, COSV59767735; called by muse, mutect2
- KIF5A | c.1072del p.E358Rfs*10 | Frame Shift Del (DEL) | VAF 9/62 reads (15%) | catalogued as COSV54059472; called by mutect2, pindel, varscan2
- KLRC3 | c.601G>T p.D201Y | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.975); catalogued as rs911005936, COSV101122936; called by muse, mutect2, varscan2
- KRT20 | c.919-1G>T p.X307_splice | Splice Site (SNP) | VAF 8/72 reads (11%) | catalogued as COSV99391411, COSV99391628; called by muse, mutect2
- LACC1 | c.815A>G p.Q272R | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as COSV100354818; called by muse, mutect2, varscan2
- LILRA1 | c.1079C>A p.A360E | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs919874018, COSV52182057, COSV52185670; called by muse, mutect2, varscan2
- LILRB4 | c.278C>A p.A93E | Missense Mutation (SNP) | VAF 29/221 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV54409020; called by muse, mutect2, varscan2
- LPIN1 | c.1123G>T p.A375S | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV56771614; called by muse, mutect2, varscan2
- LRFN5 | c.396C>A p.N132K | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53277199; called by muse, mutect2
- LRP1B | c.5494C>A p.Q1832K | Missense Mutation (SNP) | VAF 11/122 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV67279827; called by muse, mutect2, varscan2
- LRRC46 | c.514C>A p.R172S | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.067); catalogued as COSV51637571; called by muse, mutect2, varscan2
- LRRIQ3 | c.1508T>A p.L503Q | Missense Mutation (SNP) | VAF 21/196 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as COSV63050674; called by muse, mutect2, varscan2
- LURAP1L | c.347G>T p.R116L | Missense Mutation (SNP) | VAF 29/179 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV100070913, COSV100070963; called by muse, mutect2, varscan2
- LYST | c.7114A>T p.K2372* | Nonsense Mutation (SNP) | VAF 67/353 reads (19%) | catalogued as COSV67714940; called by muse, mutect2, varscan2
- MAGEC3 | c.117G>T p.Q39H | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.781); catalogued as COSV53580309; called by muse, mutect2, varscan2
- MAP2 | c.4190G>T p.R1397M | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52288976; called by muse, mutect2
- MAPKBP1 | c.1258G>T p.D420Y (on ENST00000456763 / NM_001128608.2; = p.D414Y on NM_014994.3) | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52967520; called by muse, mutect2, varscan2
- MAST1 | c.182C>G p.P61R | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52256060; called by muse, mutect2, varscan2
- MMP2 | c.589C>A p.P197T | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV54605756; called by muse, mutect2, varscan2
- MRC2 | c.2050A>T p.K684* | Nonsense Mutation (SNP) | VAF 4/28 reads (14%) | catalogued as COSV57645113; called by muse, mutect2
- MS4A4A | c.635G>T p.C212F | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV59703684; called by muse, mutect2, varscan2
- MTOR | c.912G>T p.M304I | Missense Mutation (SNP) | VAF 17/147 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV63878992; called by muse, mutect2, varscan2
- MUC16 | c.25553C>A p.T8518N | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.446); catalogued as COSV67456535, COSV67497663; called by muse, mutect2, varscan2
- MUC16 | c.1304C>A p.T435K | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.026); catalogued as COSV67497673; called by muse, mutect2, varscan2
- MUC2 | c.2590G>A p.G864R | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs757922883; called by muse, mutect2
- MYO5B | c.3780G>C p.E1260D | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV53232740; called by muse, mutect2, varscan2
- MYOM2 | c.937C>T p.R313C | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs368565089, COSV50786188; called by muse, mutect2, varscan2
- MYOM2 | c.3059C>A p.S1020* | Nonsense Mutation (SNP) | VAF 9/47 reads (19%) | catalogued as COSV50705365, COSV50753905; called by muse, mutect2, varscan2
- MYT1 | c.1012C>T p.P338S | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.218); catalogued as COSV60514633; called by muse, mutect2, varscan2
- NCKAP5 | c.1250C>A p.P417H | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100494663; called by muse, mutect2, varscan2
- NDN | c.331del p.V111Sfs*7 | Frame Shift Del (DEL) | VAF 8/55 reads (15%) | catalogued as COSV59359324; called by mutect2, pindel, varscan2
- NEDD1 | c.486C>A p.N162K | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV57147172; called by muse, mutect2, varscan2
- NETO1 | c.739A>T p.K247* | Nonsense Mutation (SNP) | VAF 33/140 reads (24%) | catalogued as COSV55016143; called by muse, mutect2, varscan2
- NEXMIF | c.2988G>T p.M996I | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV50153910; called by muse, mutect2, varscan2
- NEXMIF | c.640G>A p.A214T | Missense Mutation (SNP) | VAF 27/140 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.322); catalogued as COSV50155731; called by muse, mutect2, varscan2
- NPAP1 | c.2765C>G p.P922R | Missense Mutation (SNP) | VAF 9/120 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.32); catalogued as COSV61511989; called by muse, mutect2
- NRCAM | c.539G>A p.W180* (on ENST00000379028 / NM_001371124.1; = p.W174* on NM_005010.4 and 21 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 4/62 reads (6%) | catalogued as COSV61050605; called by muse, mutect2
- NRG3 | c.2066C>A p.T689K (on ENST00000404547 / NM_001370084.1; = p.T665K on NM_001010848.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100932452, COSV64559422, COSV64586615; called by muse, mutect2, varscan2
- NUP205 | c.4724G>C p.R1575T | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.112); catalogued as COSV53666883; called by muse, mutect2, varscan2
- OLFM1 | c.1208G>T p.G403V (on ENST00000371793 / NM_001282611.2; = p.G385V on NM_014279.5) | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99424425; called by muse, mutect2, varscan2
- OR10AG1 | c.433C>A p.P145T | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.513); catalogued as COSV56632669, COSV56635181; called by muse, mutect2, varscan2
- OR10J3 | c.496G>T p.G166C | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as COSV100171917; called by muse, mutect2, varscan2
- OR10T2 | c.373G>T p.V125L | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.313); catalogued as COSV57783830; called by muse, mutect2, varscan2
- OR2A14 | c.856C>A p.P286T | Missense Mutation (SNP) | VAF 44/237 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV68718752; called by muse, mutect2, varscan2
- OR2L3 | c.605C>A p.T202N | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.903); catalogued as COSV63456492; called by muse, varscan2
- OR2M7 | c.398C>A p.T133N | Missense Mutation (SNP) | VAF 38/234 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as COSV58740956; called by muse, mutect2, varscan2
- OR51I2 | c.404T>A p.V135E | Missense Mutation (SNP) | VAF 24/138 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.399); catalogued as COSV58300437; called by muse, mutect2, varscan2
- OR52B6 | c.926C>T p.P309L | Missense Mutation (SNP) | VAF 27/163 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs765805385, COSV61448417; called by muse, mutect2, varscan2
- OR52E2 | c.278G>T p.G93V | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100384952, COSV58612350; called by muse, mutect2, varscan2
- OR5K3 | c.397C>A p.H133N | Missense Mutation (SNP) | VAF 54/142 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs773659638, COSV67350143, COSV67350780; called by muse, mutect2, varscan2
- OR5L2 | c.550C>A p.L184I | Missense Mutation (SNP) | VAF 32/255 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.122); catalogued as rs142870159; called by muse, mutect2, varscan2
- OR8H2 | c.559C>A p.L187M | Missense Mutation (SNP) | VAF 40/244 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV57947694; called by muse, mutect2, varscan2
- OTOF | c.4500+1G>T p.X1500_splice (on ENST00000272371 / NM_194248.3; = p.X733_splice on NM_004802.4) | Splice Site (SNP) | VAF 5/38 reads (13%) | catalogued as COSV99719200; called by muse, mutect2, varscan2
- PACS1 | c.1052T>C p.L351P | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.997); catalogued as COSV57700266; called by muse, mutect2, varscan2
- PADI2 | c.1009G>T p.V337F | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV64946851; called by muse, mutect2, varscan2
- PAMR1 | c.98G>T p.C33F | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs757733725, COSV53517007; called by muse, mutect2, varscan2
- PARP4 | c.1311G>T p.L437F | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.312); catalogued as COSV67964511; called by muse, mutect2, varscan2
- PCDHGA6 | c.299C>A p.P100Q | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.258); catalogued as COSV53975807, COSV54043909; called by muse, mutect2, varscan2
- PCDHGB4 | c.310C>A p.L104M | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99548365; called by muse, mutect2, varscan2
- PCNX1 | c.6871G>T p.G2291C | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53103052; called by muse, mutect2, varscan2
- PCSK5 | c.379A>G p.N127D | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.075); catalogued as COSV65097391; called by muse, mutect2, varscan2
- PDE11A | c.2580C>A p.N860K | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.7); catalogued as rs780232099, COSV53710547; called by muse, mutect2, varscan2
- PHLDB1 | c.1084A>T p.S362C | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV61882263; called by mutect2, varscan2
- PIP5K1A | c.1684C>T p.H562Y (on ENST00000368888 / NM_001135638.2; = p.H549Y on NM_003557.3) | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.063); catalogued as COSV62960365; called by muse, mutect2, varscan2
- PLCB4 | c.3505C>A p.R1169S (on ENST00000278655 / NM_182797.3; = p.P1181Q on NM_000933.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.062); catalogued as COSV53805537, COSV99597126; called by muse, mutect2, varscan2
- PLPPR4 | c.1268C>T p.P423L | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as COSV64567856; called by muse, mutect2
- PNPLA1 | c.1423G>T p.V475L (on ENST00000394571 / NM_001374623.1; = p.V380L on NM_173676.2) | Missense Mutation (SNP) | VAF 34/174 reads (20%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.029); catalogued as COSV100463829, COSV57235130; called by muse, mutect2, varscan2
- PNPLA7 | c.2039G>A p.R680H | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs780447108, COSV53000702; called by muse, mutect2
- POSTN | c.2270-2A>G p.X757_splice | Splice Site (SNP) | VAF 24/107 reads (22%) | catalogued as COSV65714902; called by muse, mutect2, varscan2
- POT1 | c.410G>T p.R137L | Missense Mutation (SNP) | VAF 54/180 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587777475, CM144558, COSV62931229, COSV62935193; called by muse, mutect2, varscan2
- POT1 | c.227G>T p.G76V | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62935205; called by muse, mutect2, varscan2
- POTEF | c.341A>T p.K114M | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.642); catalogued as COSV62544974; called by muse, mutect2, varscan2
- PPM1E | c.1195G>C p.V399L | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.857); catalogued as COSV57580914; called by muse, mutect2, varscan2
- PPP1R3A | c.3074G>T p.R1025M | Missense Mutation (SNP) | VAF 35/271 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.747); catalogued as COSV52894098; called by muse, mutect2, varscan2
- PRAMEF2 | c.64G>C p.A22P | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.022); catalogued as COSV53579931; called by muse, mutect2, varscan2
- PRELP | c.755A>G p.N252S | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58117728; called by muse, mutect2, varscan2
- PTAFR | c.257C>A p.P86H | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.041); catalogued as COSV59536404; called by muse, mutect2
- PTGES3L-AARSD1 | c.1426G>T p.G476C (on ENST00000421990 / NM_001136042.2; = p.G458C on NM_025267.3) | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64184832; called by muse, mutect2, varscan2
- PTPN5 | c.132C>A p.D44E | Missense Mutation (SNP) | VAF 26/165 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.723); catalogued as COSV62128918; called by muse, mutect2, varscan2
- PTPRD | c.3536G>C p.S1179T | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV61985528; called by muse, mutect2, varscan2
- PTPRO | c.3570G>T p.Q1190H (on ENST00000281171 / NM_030667.3; = p.Q1162H on NM_002848.4) | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99841945; called by muse, mutect2, varscan2
- PXDNL | c.1880C>G p.S627C | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV62494136; called by muse, varscan2
- RAB38 | c.623G>T p.C208F | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.804); catalogued as COSV54716458; called by muse, mutect2, varscan2
- RAB4A | c.579G>T p.Q193H | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV64207137; called by muse, mutect2, varscan2
- RAI2 | c.1290G>T p.M430I | Missense Mutation (SNP) | VAF 6/166 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100518568; called by muse, mutect2
- RAI2 | c.1289T>A p.M430K | Missense Mutation (SNP) | VAF 6/165 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV100518571; called by muse, mutect2
- RASAL1 | c.553G>T p.E185* | Nonsense Mutation (SNP) | VAF 14/52 reads (27%) | catalogued as COSV55660198; called by muse, mutect2, varscan2
- REC8 | c.1330G>A p.E444K | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1385465833, COSV61018624; called by muse, mutect2, varscan2
- RET | c.1679C>A p.P560H | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100394857; called by muse, mutect2, varscan2
- RHAG | c.304C>A p.Q102K | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs890327240, COSV57706693; called by muse, mutect2, varscan2
- RIMBP2 | c.1084T>A p.C362S | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.977); catalogued as COSV55485474; called by muse, mutect2, varscan2
- RNF40 | c.875G>C p.R292P | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61213819, COSV61216920; called by muse, mutect2, varscan2
- RXFP1 | c.1465G>A p.G489R | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100314239, COSV57048985, COSV57057394; called by muse, mutect2, varscan2
- SALL1 | c.2857C>A p.P953T | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.024); catalogued as rs767713070, COSV99192229; called by muse, mutect2, varscan2
- SAMD9 | c.2117T>A p.V706D | Missense Mutation (SNP) | VAF 57/209 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV66077860; called by muse, mutect2, varscan2
- SC5D | c.593A>T p.Y198F | Missense Mutation (SNP) | VAF 7/180 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV50614089; called by muse, mutect2
- SCARA5 | c.1171A>G p.M391V | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV61574472; called by muse, mutect2, varscan2
- SCN3B | c.397C>A p.P133T | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.726); catalogued as rs781163714, COSV54801524; called by muse, mutect2, varscan2
- SEMA3A | c.1076G>A p.R359K | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.072); catalogued as COSV54890313; called by muse, mutect2, varscan2
- SERPING1 | c.1337T>A p.V446E | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV53544534; called by muse, mutect2, varscan2
- SIGLEC14 | c.649C>T p.R217C | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.759); catalogued as COSV55779392; called by muse, mutect2, varscan2
- SIGLEC8 | c.684G>T p.L228F | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.96); PolyPhen benign (0.009); catalogued as COSV58476090; called by muse, mutect2, varscan2
- SIMC1 | c.148A>G p.R50G (on ENST00000443967 / NM_001308196.1; = p.R69G on NM_001308195.2) | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as rs550182179, COSV57907942; called by muse, mutect2, varscan2
- SLC26A3 | c.818C>A p.S273Y | Missense Mutation (SNP) | VAF 32/200 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as COSV60643067; called by muse, mutect2, varscan2
- SLC5A7 | c.689G>T p.G230V | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50906985; called by muse, mutect2, varscan2
- SLC9C2 | c.2522T>C p.L841P | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62949936; called by muse, mutect2, varscan2
- SLCO2B1 | c.374T>A p.V125E | Missense Mutation (SNP) | VAF 26/158 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV56940019; called by muse, mutect2, varscan2
- SLIT1 | c.2798C>A p.P933Q | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV56600308; called by muse, mutect2, varscan2
- SLIT1 | c.2297+2T>A p.X766_splice | Splice Site (SNP) | VAF 9/57 reads (16%) | catalogued as COSV56599848, COSV56600316; called by muse, mutect2, varscan2
- SLITRK5 | c.2133C>A p.N711K | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.391); catalogued as COSV100281291; called by muse, mutect2, varscan2
- SNX18 | c.1303A>T p.T435S | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.36); PolyPhen benign (0.306); catalogued as COSV57987967, COSV57990394, COSV57992704; called by muse, mutect2
- SORCS1 | c.1461C>A p.N487K | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.313); catalogued as COSV53909227; called by muse, mutect2
- SPNS1 | c.613G>T p.A205S | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as COSV57956965; called by muse, mutect2, varscan2
- SPRR3 | c.443A>T p.K148M | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); catalogued as COSV99768815; called by muse, mutect2, varscan2
- SPTBN4 | c.5443G>A p.A1815T | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs771211249, COSV100152303; called by muse, mutect2, varscan2
- SYT3 | c.578G>T p.G193V | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as rs1197818694, COSV58898380, COSV58899407; called by muse, mutect2, varscan2
- TAC1 | c.102G>T p.W34C | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59988264; called by muse, mutect2, varscan2
- TBR1 | c.802G>T p.G268* | Nonsense Mutation (SNP) | VAF 12/100 reads (12%) | catalogued as rs1553510298, COSV67419349; called by muse, mutect2
- TCERG1L | c.1680G>T p.Q560H | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV64058252, COSV64058658; called by muse, mutect2, varscan2
- TECPR1 | c.2824G>T p.E942* | Nonsense Mutation (SNP) | VAF 3/18 reads (17%) | catalogued as COSV101130804; called by muse, mutect2
- TEX47 | c.121C>A p.H41N | Missense Mutation (SNP) | VAF 38/188 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.051); catalogued as rs1163870771, COSV51880426; called by muse, mutect2
- TGFB2 | c.614A>T p.D205V | Missense Mutation (SNP) | VAF 28/164 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.102); catalogued as COSV65111389; called by muse, varscan2
- TGM4 | c.1132A>G p.I378V | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.013); catalogued as rs772093877, COSV56096919; called by muse, mutect2
- THUMPD1 | c.708G>T p.Q236H | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as COSV67263607; called by muse, mutect2, varscan2
- TLN2 | c.7606G>A p.E2536K | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.212); catalogued as rs921864392, COSV60885950; called by muse, mutect2, varscan2
- TMCO3 | c.1564A>T p.M522L | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.43); catalogued as COSV64809406; called by muse, mutect2, varscan2
- TOP3A | c.1214G>T p.R405L | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV58179588, COSV58181428; called by muse, mutect2, varscan2
- TRIP13 | c.796G>T p.A266S | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.214); catalogued as COSV51322549; called by muse, mutect2, varscan2
- UBE2D2 | c.164A>G p.H55R | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.012); catalogued as COSV54080726; called by muse, mutect2, varscan2
- UBE3C | c.1465T>A p.S489T | Missense Mutation (SNP) | VAF 27/241 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.051); catalogued as COSV61955861; called by muse, mutect2, varscan2
- UBQLN3 | c.106T>A p.S36T | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV100293997; called by muse, mutect2, varscan2
- UBR4 | c.9713G>T p.R3238L | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.144); catalogued as COSV64400728; called by muse, mutect2, varscan2
- UBXN7 | c.977G>T p.S326I | Missense Mutation (SNP) | VAF 50/160 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.881); catalogued as COSV56358127; called by muse, mutect2, varscan2
- USH2A | c.2035G>A p.G679R | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs367693972; called by muse, mutect2, varscan2
- VIT | c.1231G>T p.E411* (on ENST00000389975 / NM_001177969.1; = p.E426* on NM_053276.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 12/92 reads (13%) | catalogued as COSV64899529; called by muse, mutect2, varscan2
- VPS13A | c.5015A>C p.K1672T | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as rs554283579, COSV62440164; called by muse, mutect2, varscan2
- WWP2 | c.1403G>T p.R468L | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63128207; called by muse, mutect2, varscan2
- XPO5 | c.365A>T p.E122V | Missense Mutation (SNP) | VAF 45/151 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54835780; called by muse, mutect2, varscan2
- XYLT1 | c.1393G>T p.D465Y | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54497923; called by muse, mutect2, varscan2
- XYLT1 | c.990T>G p.F330L | Missense Mutation (SNP) | VAF 23/169 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54497928; called by muse, mutect2, varscan2
- ZIK1 | c.793A>G p.R265G | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as rs1427265733, COSV56738564, COSV56738690; called by muse, mutect2, varscan2
- ZNF208 | c.1757G>T p.C586F | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV68113371; called by muse, mutect2, varscan2
- ZNF292 | c.3655G>T p.D1219Y | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.69); PolyPhen benign (0.36); catalogued as COSV60547527; called by muse, mutect2, varscan2
- ZNF347 | c.2144G>T p.G715V | Missense Mutation (SNP) | VAF 21/172 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61971192; called by muse, mutect2, varscan2
- ZNF479 | c.696A>T p.K232N | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV58644245; called by muse, mutect2, varscan2
- ZNF534 | c.361C>T p.Q121* (on ENST00000332323 / NM_001143939.3; = p.Q108* on NM_001143938.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 6/41 reads (15%) | catalogued as COSV56516849, COSV56517132; called by mutect2, varscan2
- ZNF548 | c.1103G>T p.S368I | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.341); catalogued as rs755046123, COSV60240558, COSV60242131; called by muse, mutect2, varscan2
- ZNF551 | c.94G>T p.E32* | Nonsense Mutation (SNP) | VAF 19/130 reads (15%) | catalogued as COSV56595405; called by muse, mutect2, varscan2
- ZNF778 | c.997G>T p.G333* | Nonsense Mutation (SNP) | VAF 16/114 reads (14%) | catalogued as COSV60600430, COSV60603015; called by muse, mutect2, varscan2
- ZNF831 | c.2874G>C p.W958C | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV100926294; called by muse, varscan2
- ZSCAN5B | c.1037G>A p.G346D | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV62001294; called by muse, mutect2, varscan2
- ZSWIM2 | c.209C>A p.P70Q | Missense Mutation (SNP) | VAF 11/119 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV54579553, COSV99720609; called by muse, mutect2
- CSMD1 | c.9263C>A p.P3088Q (on ENST00000520002; = p.P3087Q on NM_033225.6) | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2
- FAM47C | c.413del p.G138Efs*13 | Frame Shift Del (DEL) | VAF 12/77 reads (16%) | called by mutect2, pindel, varscan2
- GAS2L2 | c.2512G>T p.E838* | Nonsense Mutation (SNP) | VAF 10/45 reads (22%) | called by muse, mutect2, varscan2
- IGKV1-5 | c.197C>A p.P66H | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- MRC1 | c.2333A>T p.Q778L | Missense Mutation (SNP) | VAF 51/333 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- PLD2 | c.646del p.H216Tfs*25 | Frame Shift Del (DEL) | VAF 25/149 reads (17%) | called by mutect2, pindel, varscan2
- RB1 | c.1581_1607del p.F528_I536del | In Frame Del (DEL) | VAF 6/49 reads (12%) | called by mutect2, pindel
- WDR19 | c.2671del p.H891Tfs*26 | Frame Shift Del (DEL) | VAF 6/29 reads (21%) | called by mutect2, pindel, varscan2
- AADACL2 | c.615T>C p.D205= | Silent (SNP) | VAF 31/75 reads (41%) | catalogued as COSV62932705; called by muse, mutect2, varscan2
- BRINP1 | c.57A>T p.S19= | Silent (SNP) | VAF 25/100 reads (25%) | catalogued as COSV56314620, COSV99774733; called by muse, mutect2, varscan2
- BRSK1 | c.579C>A p.S193= | Silent (SNP) | VAF 18/103 reads (17%) | catalogued as COSV58670546; called by muse, mutect2, varscan2
- C18orf25 | c.633G>T p.L211= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as COSV56369181; called by muse, mutect2, varscan2
- CCDC122 | c.789C>A p.A263= | Silent (SNP) | VAF 6/86 reads (7%) | catalogued as COSV101480977, COSV71573655; called by muse, mutect2
- CFAP46 | c.5646G>A p.L1882= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV54160407; called by muse, mutect2
- CFAP77 | c.885G>A p.Q295= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as COSV100546183; called by muse, mutect2, varscan2
- CRYAB | c.96G>T p.L32= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs782402748, COSV99909989; called by muse, mutect2, varscan2
- CRYBG2 | c.639C>G p.V213= | Silent (SNP) | VAF 4/14 reads (29%) | called by mutect2, varscan2
- CYSLTR2 | c.240G>T p.L80= | Silent (SNP) | VAF 15/81 reads (19%) | catalogued as COSV56167163; called by muse, mutect2, varscan2
- DGKZ | c.2880C>T p.P960= (on ENST00000454345 / NM_001105540.2; = p.P772= on NM_003646.4) | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV100551276, COSV58995949; called by muse, mutect2, varscan2
- DNAH9 | c.3810C>A p.S1270= | Silent (SNP) | VAF 14/95 reads (15%) | catalogued as COSV52367288, COSV99308531; called by muse, mutect2, varscan2
- DOCK10 | c.2298C>T p.H766= | Silent (SNP) | VAF 20/102 reads (20%) | catalogued as rs368832236; called by muse, mutect2, varscan2
- DUSP22 | c.306C>T p.Y102= | Silent (SNP) | VAF 14/166 reads (8%) | catalogued as rs749860501, COSV60532076; called by muse, mutect2
- DYSF | c.1149G>C p.L383= | Silent (SNP) | VAF 31/198 reads (16%) | catalogued as COSV50628166; called by muse, mutect2, varscan2
- FRMPD1 | c.4137C>A p.P1379= | Silent (SNP) | VAF 16/89 reads (18%) | catalogued as COSV100899626, COSV66703513; called by muse, mutect2, varscan2
- GH2 | c.180C>A p.A60= | Silent (SNP) | VAF 53/315 reads (17%) | catalogued as COSV60428035; called by muse, mutect2, varscan2
- HOXA1 | c.123G>T p.A41= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as COSV56067237, COSV56067938; called by muse, mutect2, varscan2
- IFNL1 | c.288C>A p.A96= | Silent (SNP) | VAF 6/61 reads (10%) | catalogued as COSV100373689; called by muse, mutect2, varscan2
- IGKV1-9 | c.351T>A p.P117= | Silent (SNP) | VAF 27/119 reads (23%) | called by muse, mutect2, varscan2
- IL1RAPL2 | c.186C>A p.T62= | Silent (SNP) | VAF 16/71 reads (23%) | catalogued as COSV61185753; called by muse, mutect2, varscan2
- IL36RN | c.304C>A p.R102= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as CM132983, COSV100697211, COSV100697304; called by muse, mutect2
- INHBE | c.696G>T p.R232= | Silent (SNP) | VAF 15/102 reads (15%) | catalogued as COSV56988404, COSV56989240; called by muse, mutect2, varscan2
- KIAA0586 | c.2685A>G p.P895= (on ENST00000619416 / NM_001244190.2; = p.P834= on NM_014749.5) | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as COSV99709077; called by muse, mutect2, varscan2
- KRT77 | c.528C>T p.A176= | Silent (SNP) | VAF 11/131 reads (8%) | catalogued as COSV59241710; called by muse, mutect2
- LILRA2 | c.396G>C p.V132= | Silent (SNP) | VAF 28/113 reads (25%) | catalogued as COSV52196515, COSV52197749; called by muse, mutect2, varscan2
- LRRC3B | c.177T>G p.P59= | Silent (SNP) | VAF 9/53 reads (17%) | catalogued as COSV101186072; called by muse, mutect2, varscan2
- MDGA2 | c.1269G>A p.E423= (on ENST00000399232 / NM_001113498.2; = p.E125= on NM_182830.4) | Silent (SNP) | VAF 9/77 reads (12%) | catalogued as rs373885586; called by muse, mutect2
- MYH3 | c.2418G>C p.V806= | Silent (SNP) | VAF 7/81 reads (9%) | catalogued as COSV56870642; called by muse, mutect2
- NBAS | c.6423C>T p.P2141= | Silent (SNP) | VAF 18/110 reads (16%) | catalogued as COSV55739370; called by muse, mutect2, varscan2
- NCKAP5 | c.1251C>A p.P417= | Silent (SNP) | VAF 16/116 reads (14%) | catalogued as COSV100494662; called by muse, mutect2, varscan2
- NDUFS1 | c.1287G>T p.V429= | Silent (SNP) | VAF 14/123 reads (11%) | catalogued as COSV99261572; called by muse, mutect2, varscan2
- NFIC | c.1179C>T p.A393= | Silent (SNP) | VAF 32/167 reads (19%) | catalogued as COSV59417317; called by muse, mutect2, varscan2
- NTRK3 | c.664C>A p.R222= | Silent (SNP) | VAF 3/34 reads (9%) | catalogued as COSV58112894, COSV58148287; called by muse, mutect2
- OLFM1 | c.1209G>T p.G403= (on ENST00000371793 / NM_001282611.2; = p.G385= on NM_014279.5) | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as COSV53276500, COSV99424431; called by muse, mutect2
- OR2F1 | c.474G>C p.V158= | Silent (SNP) | VAF 19/67 reads (28%) | catalogued as COSV67332156; called by muse, mutect2, varscan2
- OR4K15 | c.270G>C p.L90= (on ENST00000305051; = p.L66= on NM_001005486.1) | Silent (SNP) | VAF 24/166 reads (14%) | catalogued as COSV59303651; called by muse, mutect2
- OR51M1 | c.228C>A p.S76= | Silent (SNP) | VAF 22/118 reads (19%) | catalogued as COSV60784184, COSV60785607; called by muse, mutect2, varscan2
- OR52N4 | c.723T>C p.N241= | Silent (SNP) | VAF 16/166 reads (10%) | catalogued as rs1174613992, COSV57893249; called by muse, mutect2, varscan2
- PAK4 | c.168C>T p.P56= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as rs764654285, COSV58947243; called by muse, mutect2, varscan2
- PAK6 | c.1893G>T p.L631= | Silent (SNP) | VAF 6/82 reads (7%) | catalogued as COSV53047143; called by muse, mutect2
- PDCD1LG2 | c.75C>A p.V25= | Silent (SNP) | VAF 9/76 reads (12%) | catalogued as COSV67205612; called by muse, mutect2, varscan2
- PDE3A | c.606A>T p.T202= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as rs777757938, COSV62983709; called by mutect2, varscan2
- PLBD2 | c.771C>T p.L257= | Silent (SNP) | VAF 13/75 reads (17%) | catalogued as COSV55109209; called by muse, mutect2, varscan2
- PRPF40A | c.669C>A p.P223= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV100583048; called by muse, mutect2
- PTPRA | c.2352C>T p.C784= | Silent (SNP) | VAF 17/95 reads (18%) | catalogued as COSV53789343; called by muse, mutect2, varscan2
- PUM1 | c.2364T>C p.A788= | Silent (SNP) | VAF 18/133 reads (14%) | catalogued as rs1315090819, COSV57091987; called by muse, varscan2
- PWP1 | c.366G>T p.G122= | Silent (SNP) | VAF 9/99 reads (9%) | catalogued as COSV69833533; called by muse, mutect2
- QRICH2 | c.1632G>A p.L544= | Silent (SNP) | VAF 9/64 reads (14%) | catalogued as COSV53158361; called by muse, mutect2, varscan2
- RASIP1 | c.105G>A p.L35= | Silent (SNP) | VAF 8/67 reads (12%) | catalogued as COSV99711156; called by muse, mutect2, varscan2
- RP1L1 | c.3453C>G p.L1151= | Silent (SNP) | VAF 4/48 reads (8%) | catalogued as COSV66760931; called by muse, mutect2
- RRP12 | c.1161G>T p.L387= | Silent (SNP) | VAF 22/133 reads (17%) | catalogued as COSV59671863; called by muse, mutect2, varscan2
- SIPA1L3 | c.3114C>A p.I1038= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as COSV55925372; called by muse, mutect2, varscan2
- SIRPG | c.501C>A p.T167= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as COSV53810711; called by muse, mutect2, varscan2
- SLFNL1 | c.267G>C p.P89= | Silent (SNP) | VAF 9/70 reads (13%) | catalogued as COSV57235810; called by muse, mutect2, varscan2
- SNRNP35 | c.18C>G p.P6= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as COSV63472384; called by muse, mutect2, varscan2
- SPEF2 | c.3381G>T p.A1127= | Silent (SNP) | VAF 23/153 reads (15%) | catalogued as COSV100608896, COSV61554226; called by muse, mutect2, varscan2
- SPHK1 | c.1122C>G p.P374= (on ENST00000392496 / NM_001355139.2; = p.P388= on NM_021972.4) | Silent (SNP) | VAF 6/73 reads (8%) | catalogued as COSV100039602; called by muse, mutect2
- SPTA1 | c.6063G>T p.L2021= | Silent (SNP) | VAF 58/339 reads (17%) | catalogued as COSV63751984, COSV63760518; called by muse, mutect2, varscan2
- TGIF2LX | c.45G>T p.V15= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as COSV99383550; called by muse, mutect2
- TMEM236 | c.672C>A p.I224= | Silent (SNP) | VAF 23/116 reads (20%) | called by muse, mutect2, varscan2
- TMTC1 | c.2157C>A p.L719= (on ENST00000539277 / NM_001193451.2; = p.L611= on NM_175861.3) | Silent (SNP) | VAF 13/112 reads (12%) | catalogued as rs1210648860, COSV99761293; called by muse, mutect2, varscan2
- TUBB8 | c.924C>A p.G308= | Silent (SNP) | VAF 41/165 reads (25%) | catalogued as COSV59118229; called by muse, mutect2, varscan2
- UGT2B7 | c.90A>T p.A30= | Silent (SNP) | VAF 18/125 reads (14%) | catalogued as COSV59445754; called by muse, mutect2, varscan2
- USP44 | c.501A>G p.E167= | Silent (SNP) | VAF 22/108 reads (20%) | catalogued as COSV51567589; called by muse, mutect2, varscan2
- ZBED6CL | c.96A>G p.T32= | Silent (SNP) | VAF 40/223 reads (18%) | catalogued as COSV100550652; called by muse, mutect2, varscan2
- ZSWIM2 | c.210G>A p.P70= | Silent (SNP) | VAF 12/119 reads (10%) | catalogued as rs765189432, COSV54574784; called by muse, mutect2
- CCDC180 | c.3903-21C>G | Intron (SNP) | VAF 8/42 reads (19%) | catalogued as COSV100827383; called by muse, mutect2, varscan2
- CENPF | c.7830+569G>A | Intron (SNP) | VAF 6/24 reads (25%) | called by muse, mutect2
- DCHS2 | n.3899C>A | RNA (SNP) | VAF 6/36 reads (17%) | catalogued as COSV100602775; called by muse, mutect2, varscan2
- LINC01098 | n.655G>T | RNA (SNP) | VAF 19/107 reads (18%) | catalogued as rs775712184; called by muse, mutect2, varscan2
- PLXNA4 | c.1371+4347G>T | Intron (SNP) | VAF 32/103 reads (31%) | catalogued as COSV100327665; called by muse, mutect2, varscan2
- REEP5 | c.*1A>T | 3'UTR (SNP) | VAF 23/118 reads (19%) | catalogued as COSV99810126; called by mutect2, varscan2
- USH1C | c.1646+1120G>T | Intron (SNP) | VAF 25/164 reads (15%) | catalogued as rs368855735, COSV99142344; called by muse, mutect2, varscan2
